Gene-level copy-number profile of tumor specimen TCGA-86-8673-01A from TCGA case TCGA-86-8673, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Bronchiolo-alveolar carcinoma, non-mucinous; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 61.8 years (22,571 days).
Specimen TCGA-86-8673-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.64e2ab05-f92f-47e9-aa21-6fd496f130f6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-86-8673-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0fdf9d2f-0cfa-47ad-be1f-3428895696e0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 4,021; copy number 2: 37,834; copy number 3: 7,949; copy number 4: 4,996; copy number 5: 1,156; copy number 6: 2,000; copy number 7: 1,211; copy number 8: 475; copy number 11: 124; copy number 12: 36; copy number 13: 6; copy number 46: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-86-8673-01A-11D-2389-01): tumor purity 0.4, ploidy 2.56, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:59,314,110–59,314,800, 1 gene: AC008833.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,011 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–158,700,652, 693 genes, copy number 5–11 (broad region; genes not listed).
- chr1:159,535,078–165,709,968, 191 genes, copy number 8–13 (broad region; genes not listed).
- chr1:167,519,536–167,791,919, 6 genes, copy number 7: AKR1D1P1, CREG1, AL031733.1, AL031733.2, RCSD1, MPZL1.
- chr1:168,695,468–169,367,948, 13 genes, copy number 8 (within-gene range 4–8): DPT, AL135926.1, AL031275.1, LINC00626, SUMO1P2, AL135926.2, LINC00970, RPL29P7, AL031726.2, RNA5SP66, AL031726.1, ATP1B1, NME7.
- chr1:187,070,700–205,022,822, 282 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr1:209,267,798–209,380,518, 3 genes, copy number 7: ATP5MC2P1, LINC01696, LINC01698.
- chr1:214,943,123–214,988,040, 2 genes, copy number 7: AC099563.1, AC099563.2.
- chr1:224,175,476–227,980,227, 98 genes, copy number 6 (broad region; genes not listed).
- chr3:93,843,764–109,977,767, 211 genes, copy number 6 (broad region; genes not listed).
- chr3:158,496,561–158,871,821, 16 genes, copy number 6: AC106707.2, AC106707.1, MLF1, MTAPP1, AC025033.1, GFM1, LXN, AC080013.3, RARRES1, MFSD1, AC080013.1, RPL35AP9, AC080013.2, AC080013.4, GPR79, AC092999.1.
- chr3:165,772,904–167,959,082, 29 genes, copy number 6: BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1, LINC01326, AC072046.2, RN7SKP298, PSAT1P4, AC072046.1, CBX1P5, AC069439.2, AC069439.1, PPIAP74, ZBBX, LINC01327, SERPINI2, WDR49, PDCD10, HMGN1P8, SERPINI1, AC079822.1, LRRC77P, AC026353.1, MEMO1P3, AC128713.1, HMGN2P26.
- chr5:58,198–45,895,970, 710 genes, copy number 7 (broad region; genes not listed).
- chr6:125,956,770–125,980,244, 2 genes, copy number 13: HINT3, RNA5SP216.
- chr7:70,972–51,864,798, 903 genes, copy number 5–8 (broad region; genes not listed).
- chr7:91,030,149–159,233,377, 1,406 genes, copy number 6 (broad region; genes not listed).
- chr10:25,813,811–28,623,112, 59 genes, copy number 6: RNA5SP306, RNU6-632P, AL358612.1, MYO3A, GAD2, AL355798.1, APBB1IP, RNA5SP307, AL160287.1, FAM238A, AL390961.1, FAM238B, SELENOOLP, AL390961.3, PDSS1, HSPA8P3, AL390961.2, ABI1, AL139404.1, RNU6-946P, FAM238C, ANKRD26, RNU6-490P, YME1L1, MASTL, ACBD5, RNU2-24P, RNU7-12P, AL160291.1, LRRC37A6P, ARMC4P1, AL355493.6, RNU6-666P, AL355493.1, RNU6-452P, LINC02673, FAM210CP, TRIAP1P1, PTCHD3, RAB18, LINC02680, MKX, MKX-AS1, ARMC4, RN7SKP132, RPL36AP55, AL390866.1, MRPS21P5, MPP7, AL355501.1, MIR8086, MPP7-DT, ZNF101P1, U3, LINC02652, RPSAP10, RN7SKP39, WAC-AS1, WAC.
- chr11:25,588,475–26,047,598, 5 genes, copy number 5: RPL36AP40, AC100770.1, LINC02699, AC013799.1, AC024341.1.
- chr11:26,244,640–26,269,415, 1 gene, copy number 5: AC021698.1.
- chr14:36,213,200–36,656,163, 6 genes, copy number 5–46 (within-gene range 2–46): AL162511.1, RN7SKP21, MBIP, AL132857.1, DPPA3P2, RNU7-93P.
- chr16:29,350,746–31,794,869, 208 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr16:70,802,084–71,230,722, 4 genes, copy number 5 (within-gene range 2–5): HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1.
- chr20:44,475,874–49,299,600, 163 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,737. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
